Somatic mutation profile of tumor specimen TCGA-AR-A1AN-01A (aliquot TCGA-AR-A1AN-01A-11D-A12Q-09) from TCGA case TCGA-AR-A1AN, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 46.5 years (16,974 days).
Specimen TCGA-AR-A1AN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) add8de55-c126-4782-8e2d-b261a3a5ad51.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AR-A1AN-10A (Blood Derived Normal), aliquot TCGA-AR-A1AN-10A-01D-A12Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/614f0b2d-0db5-43d7-860e-25939e433dba

The open-access MAF lists 26 somatic variants for this specimen: 22 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 18, Silent 4, Splice Site 2, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.328del p.R110Vfs*13 | Frame Shift Del (DEL) | VAF 10/35 reads (29%) | catalogued as rs587780066, CD136796, COSV52684761, COSV53551526; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ATF3 | c.498G>C p.E166D | Missense Mutation (SNP) | VAF 19/164 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV54235930, COSV99674460; called by muse, mutect2, varscan2
- ATP4A | c.12+1G>A p.X4_splice | Splice Site (SNP) | VAF 15/56 reads (27%) | catalogued as rs370980463; called by muse, mutect2, varscan2
- BCORL1 | c.5008G>A p.E1670K | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.303); catalogued as rs1000714095, COSV54397623; called by muse, mutect2, varscan2
- CCDC24 | c.346C>T p.H116Y | Missense Mutation (SNP) | VAF 115/400 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.342); catalogued as COSV58844127; called by muse, mutect2, varscan2
- COL24A1 | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs200728036, COSV65307350; called by muse, mutect2, varscan2
- DNAJC1 | c.361C>T p.R121* | Nonsense Mutation (SNP) | VAF 112/325 reads (34%) | catalogued as rs144492315; called by muse, mutect2, varscan2
- GRM6 | c.1315C>T p.R439W | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs147576667; called by muse, mutect2, varscan2
- HCFC1 | c.4481C>T p.P1494L | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.715); catalogued as rs1446971324, COSV60072940; called by muse, mutect2, varscan2
- KHNYN | c.368G>T p.G123V | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52160390, COSV99249481; called by muse, mutect2
- KPNA3 | c.903+2T>C p.X301_splice | Splice Site (SNP) | VAF 29/167 reads (17%) | catalogued as COSV99903981; called by muse, mutect2, varscan2
- MAGEE2 | c.785C>G p.T262R | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV64897812; called by muse, mutect2, varscan2
- MPDZ | c.370C>G p.Q124E | Missense Mutation (SNP) | VAF 97/327 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.021); catalogued as COSV59938138, COSV59943500; called by muse, mutect2, varscan2
- NAE1 | c.1268T>A p.I423K | Missense Mutation (SNP) | VAF 15/290 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as COSV51975397, COSV99323008; called by muse, mutect2
- PPAN-P2RY11 | c.1204C>G p.L402V | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as rs779050709, COSV53453263; called by muse, mutect2, varscan2
- PRCP | c.694C>T p.H232Y | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV57289103; called by muse, mutect2, varscan2
- RAB6C | c.229A>G p.S77G | Missense Mutation (SNP) | VAF 41/222 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.893); catalogued as COSV101308475; called by muse, varscan2
- RUNX1 | c.401T>C p.L134P (on ENST00000344691 / NM_001001890.3; = p.L161P on NM_001754.5) | Missense Mutation (SNP) | VAF 65/241 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55869984; called by muse, mutect2, varscan2
- TSHZ3 | c.107C>T p.T36M | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as rs201181883; called by muse, mutect2, varscan2
- TSR2 | c.349C>G p.Q117E | Missense Mutation (SNP) | VAF 50/194 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.446); catalogued as COSV64308837; called by muse, mutect2, varscan2
- UNC13A | c.1507G>A p.V503M | Missense Mutation (SNP) | VAF 68/267 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.791); catalogued as COSV53197529; called by muse, mutect2, varscan2
- WWP2 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 64/186 reads (34%) | SIFT tolerated (0.58); PolyPhen benign (0.226); catalogued as rs1029698891, COSV63125349; called by muse, mutect2, varscan2
- HCN1 | c.2640C>T p.D880= | Silent (SNP) | VAF 29/126 reads (23%) | catalogued as rs768551046, COSV57506534; called by muse, mutect2, varscan2
- MAGEB16 | c.444G>A p.E148= | Silent (SNP) | VAF 50/153 reads (33%) | catalogued as COSV67874014; called by muse, mutect2, varscan2
- OR2A1 | c.246G>A p.A82= | Silent (SNP) | VAF 32/178 reads (18%) | catalogued as rs755391311, COSV68822778; called by muse, mutect2, varscan2
- POU2F3 | c.1032C>T p.A344= | Silent (SNP) | VAF 41/128 reads (32%) | catalogued as COSV52794378; called by muse, mutect2, varscan2
